Somatic mutation profile of tumor specimen TCGA-A2-A04P-01A (aliquot TCGA-A2-A04P-01A-31D-A128-09) from TCGA case TCGA-A2-A04P, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 36.2 years (13,238 days).
Specimen TCGA-A2-A04P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08daea4d-227d-4902-ae92-d0101ba61fde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A04P-10A (Blood Derived Normal), aliquot TCGA-A2-A04P-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1300b41-2226-47a7-ad0a-08aae77d7c3a

The open-access MAF lists 142 somatic variants for this specimen: 115 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 23, Frame Shift Del 7, Splice Site 4, In Frame Del 3, Nonsense Mutation 3, Splice Region 3, Intron 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 3132/3192 reads (98%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACKR4 | c.802A>G p.I268V | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.191); catalogued as rs753713017, COSV51443592; called by muse, mutect2, varscan2
- ADAD1 | c.363T>G p.G121= | Splice Region (SNP) | VAF 151/393 reads (38%) | catalogued as COSV56643603, COSV56647716; called by muse, mutect2, varscan2
- AGO4 | c.1288C>G p.R430G | Missense Mutation (SNP) | VAF 89/323 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV64618908; called by muse, mutect2, varscan2
- AKAP4 | c.2066T>A p.M689K | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.227); catalogued as COSV62075611; called by muse, mutect2, varscan2
- AKAP9 | c.5773C>G p.L1925V (on ENST00000359028; = p.L1893V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV62359039; called by muse, mutect2, varscan2
- ASB9 | c.593G>A p.G198D | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as rs780881880, COSV66852413; called by muse, mutect2, varscan2
- ATF4 | c.60C>G p.F20L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.294); catalogued as COSV57478102, COSV57480890; called by muse, mutect2, varscan2
- BIN2 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57208379; called by muse, mutect2, varscan2
- BRCA2 | c.9616C>G p.Q3206E | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.417); catalogued as rs80359233, COSV101200918; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- BVES | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.376); catalogued as COSV58950226; called by muse, mutect2, varscan2
- C10orf71 | c.1720A>G p.K574E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV60514095; called by muse, mutect2, varscan2
- CD163 | c.3358T>C p.S1120P | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.184); catalogued as COSV63138010; called by muse, mutect2
- CEP95 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 168/502 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV56751652; called by muse, mutect2, varscan2
- CHD7 | c.4660G>T p.D1554Y | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV71115048; called by muse, mutect2
- CNGB3 | c.210A>T p.Q70H | Missense Mutation (SNP) | VAF 177/383 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.737); catalogued as COSV60699319; called by muse, mutect2, varscan2
- CNTNAP4 | c.3562C>A p.P1188T | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs540496086, COSV56702741; called by muse, mutect2, varscan2
- CRTC2 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57845932; called by muse, mutect2
- CYB5R1 | c.298C>G p.P100A | Missense Mutation (SNP) | VAF 103/292 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65917427; called by muse, mutect2, varscan2
- DHX58 | c.872T>A p.L291Q | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52428502; called by muse, mutect2, varscan2
- DPP8 | c.308-2A>T p.X103_splice (on ENST00000341861 / NM_001320875.2; = p.X87_splice on NM_017743.6) | Splice Site (SNP) | VAF 83/142 reads (58%) | catalogued as COSV55683857; called by muse, mutect2, varscan2
- DYNC2H1 | c.7225G>C p.G2409R | Missense Mutation (SNP) | VAF 108/208 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV62108255; called by muse, mutect2, varscan2
- EEF2 | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58581104; called by muse, mutect2
- EMILIN2 | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54428183; called by muse, mutect2, varscan2
- ERBB3 | c.3505A>C p.T1169P | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57264618; called by muse, mutect2, varscan2
- FAM135B | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50543075; called by muse, mutect2, varscan2
- FARS2 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 65/522 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV51176866; called by muse, mutect2, varscan2
- FASLG | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV60681091; called by muse, mutect2, varscan2
- GJA4 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV60726245; called by muse, mutect2, varscan2
- GRIN3B | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366648289, COSV52263894; called by muse, mutect2, varscan2
- GRM3 | c.1912C>G p.P638A | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV64469849, COSV64480473; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1410-2A>G p.X470_splice | Splice Site (SNP) | VAF 14/132 reads (11%) | catalogued as COSV99735451; called by muse, mutect2
- GUF1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575851684, COSV99877462; called by muse, mutect2
- HEYL | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 11/114 reads (10%) | catalogued as rs753352796, COSV65722125; called by muse, mutect2
- HGSNAT | c.1521C>G p.F507L | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV52819456; called by muse, mutect2, varscan2
- HIPK1 | c.2477A>G p.N826S | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.931); catalogued as COSV61250991; called by muse, mutect2, varscan2
- HOOK3 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV56888509; called by muse, mutect2, varscan2
- HRNR | c.5816A>C p.H1939P | Missense Mutation (SNP) | VAF 44/1492 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as COSV100913903; called by muse, mutect2
- IL10RB | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs770606336, COSV51618374; called by muse, mutect2, varscan2
- IL1RAPL1 | c.2088G>T p.W696C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56305269; called by muse, mutect2, varscan2
- ILKAP | c.1147del p.V383Sfs*3 | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | catalogued as COSV54519399, COSV54520473; called by mutect2, varscan2
- INTS1 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs774102668, COSV67180044; called by muse, mutect2, varscan2
- IQCF1 | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV58824189; called by muse, mutect2, varscan2
- IRS4 | c.1369T>A p.S457T | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV64536211; called by muse, mutect2, varscan2
- KCNAB1 | c.161A>T p.Q54L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV67490866; called by muse, mutect2, varscan2
- KCNJ4 | c.509C>A p.T170N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV57859002; called by muse, mutect2, varscan2
- KLHL32 | c.623G>T p.W208L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV65115284; called by muse, mutect2, varscan2
- MAGEA1 | c.836T>C p.V279A | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV63119363; called by muse, mutect2, varscan2
- MRC2 | c.4147G>T p.A1383S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV57641673, COSV57645123; called by muse, mutect2
- MROH8 | c.1859A>G p.E620G | Missense Mutation (SNP) | VAF 72/109 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV54125775; called by muse, mutect2, varscan2
- MTHFD1 | c.1691C>G p.S564C | Missense Mutation (SNP) | VAF 68/101 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV53704211; called by muse, mutect2, varscan2
- MUC17 | c.9971T>C p.I3324T | Missense Mutation (SNP) | VAF 178/492 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs761171920, COSV100074954; called by muse, mutect2, varscan2
- MYO18A | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1226247663, COSV62864502; called by muse, mutect2, varscan2
- OGDH | c.1560G>A p.M520I | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.953); catalogued as COSV56057925; called by muse, mutect2, varscan2
- OR9A2 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63307175; called by muse, mutect2, varscan2
- OTOGL | c.3781C>G p.L1261V (on ENST00000547103; = p.L1252V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV72007613; called by muse, mutect2, varscan2
- PACSIN2 | c.1349G>C p.G450A | Missense Mutation (SNP) | VAF 105/238 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54323986; called by muse, mutect2, varscan2
- PAK3 | c.1506A>C p.R502S (on ENST00000262836 / NM_001324328.2; = p.R487S on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV53281222; called by muse, mutect2, varscan2
- PCDHA13 | c.1549G>A p.V517M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56480351, COSV56504864; called by muse, mutect2, varscan2
- PCDHGB4 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 94/136 reads (69%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV53892355; called by muse, mutect2, varscan2
- PDLIM4 | c.932A>T p.K311M | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV53805564; called by muse, mutect2, varscan2
- PGLS | c.639+2T>A p.X213_splice | Splice Site (SNP) | VAF 55/162 reads (34%) | catalogued as COSV53115589; called by muse, mutect2, varscan2
- PHEX | c.1727T>C p.V576A | Missense Mutation (SNP) | VAF 118/508 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as CD111063, COSV65079490; called by muse, mutect2, varscan2
- PLEKHB2 | c.591C>G p.N197K (on ENST00000409279; = p.N196K on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV52174550, COSV52175697; called by muse, mutect2, varscan2
- PPRC1 | c.4384C>T p.H1462Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.25); catalogued as rs780258251, COSV53389008; called by muse, mutect2, varscan2
- PSMD1 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 171/238 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs745401053, COSV58084059; called by muse, mutect2, varscan2
- PTPRO | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); catalogued as COSV55524152; called by muse, mutect2, varscan2
- PYROXD1 | c.1459G>C p.D487H | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV53712229; called by muse, mutect2, varscan2
- RBBP9 | c.192C>G p.H64Q | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV61500402; called by muse, mutect2
- RBM11 | c.402A>T p.L134F | Missense Mutation (SNP) | VAF 102/488 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV68748417; called by muse, mutect2
- RBM19 | c.2599A>G p.M867V | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV55699155; called by muse, mutect2, varscan2
- RBM27 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 135/179 reads (75%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV54595240; called by muse, mutect2, varscan2
- ROBO2 | c.3065G>T p.S1022I | Missense Mutation (SNP) | VAF 92/151 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.391); catalogued as COSV59942511; called by muse, mutect2, varscan2
- RPP38 | c.245T>C p.I82T | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65383420; called by muse, mutect2, varscan2
- RPTOR | c.2297G>C p.S766T | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV60819520; called by muse, mutect2, varscan2
- RYR2 | c.849G>T p.A283= | Splice Region (SNP) | VAF 47/155 reads (30%) | catalogued as COSV63718039; called by muse, mutect2, varscan2
- SALL1 | c.2707T>C p.S903P | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV51765137; called by muse, mutect2, varscan2
- SEMA4D | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 23/104 reads (22%) | catalogued as COSV59401573; called by muse, mutect2, varscan2
- SETDB1 | c.2536G>T p.G846C | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54993247; called by muse, mutect2, varscan2
- SLC4A4 | c.2167G>A p.A723T (on ENST00000264485 / NM_001098484.3; = p.A679T on NM_003759.4) | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV52640016; called by muse, mutect2
- SLCO1C1 | c.1452G>C p.E484D | Missense Mutation (SNP) | VAF 117/392 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV56881043; called by muse, mutect2, varscan2
- SOS1 | c.701C>G p.S234* | Nonsense Mutation (SNP) | VAF 15/89 reads (17%) | catalogued as COSV67677883; called by muse, mutect2, varscan2
- SPTBN5 | c.340T>G p.F114V | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV58028806; called by mutect2, varscan2
- SRPK1 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV60416652; called by muse, mutect2, varscan2
- SSC4D | c.1505G>T p.W502L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1477254007, COSV51884544; called by muse, mutect2
- STK35 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV55693134; called by muse, mutect2
- STRADA | c.1012G>T p.D338Y (on ENST00000336174 / NM_001363786.1; = p.D301Y on NM_153335.6) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV99368714; called by muse, mutect2
- TANC1 | c.2433G>A p.M811I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs777052839, COSV55098263; called by muse, mutect2, varscan2
- TAS2R31 | c.372A>C p.R124S | Missense Mutation (SNP) | VAF 132/213 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV66831316; called by muse, mutect2, varscan2
- TDRD1 | c.1142T>C p.V381A | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV52596966; called by muse, mutect2, varscan2
- TEX15 | c.4295G>C p.S1432T (on ENST00000256246; = p.S1815T on NM_001350162.2) | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV56354929; called by muse, mutect2, varscan2
- TNFAIP3 | c.1439G>A p.S480N | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52802693; called by muse, mutect2
- TNRC6B | c.4778G>T p.R1593M (on ENST00000454349 / NM_001162501.2; = p.R1483M on NM_015088.3) | Missense Mutation (SNP) | VAF 101/247 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57309066; called by muse, mutect2, varscan2
- TP53 | c.323del p.G108Vfs*15 | Frame Shift Del (DEL) | VAF 21/44 reads (48%) | catalogued as COSV53329872; called by mutect2, pindel, varscan2
- TSHZ3 | c.1603A>T p.N535Y | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53684293; called by muse, mutect2, varscan2
- TTC23 | c.1109G>C p.G370A | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50444898; called by muse, mutect2
- TTN | c.38098G>A p.E12700K (on ENST00000591111; = p.E5276K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/164 reads (5%) | PolyPhen possibly damaging (0.562); catalogued as COSV100628621; called by muse, mutect2
- UBE2J2 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59574070; called by muse, mutect2, varscan2
- UFL1 | c.1609A>G p.I537V | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.024); catalogued as rs749425862, COSV65150803; called by muse, mutect2, varscan2
- UNC5C | c.908G>C p.S303T | Missense Mutation (SNP) | VAF 94/158 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV71662586; called by muse, mutect2, varscan2
- USP26 | c.2326A>T p.T776S | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV100896753, COSV63709868; called by muse, mutect2
- USP37 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.494); catalogued as rs1344268862, COSV51447694; called by muse, mutect2, varscan2
- VAC14 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV55758353; called by muse, mutect2, varscan2
- VWF | c.7551C>T p.V2517= | Splice Region (SNP) | VAF 35/45 reads (78%) | catalogued as rs145955543; called by muse, mutect2, varscan2
- WTAP | c.152A>C p.D51A | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.78); catalogued as COSV61610632; called by muse, mutect2, varscan2
- ACVR2A | c.307del p.C103Vfs*47 | Frame Shift Del (DEL) | VAF 113/320 reads (35%) | called by mutect2, pindel, varscan2
- CCDC40 | c.2089_2095del p.E697Tfs*4 | Frame Shift Del (DEL) | VAF 16/156 reads (10%) | called by mutect2, varscan2
- CTAGE6 | c.916_927del p.N306_D309del | In Frame Del (DEL) | VAF 45/317 reads (14%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.1375_1401del p.R459_K467del | In Frame Del (DEL) | VAF 134/280 reads (48%) | called by mutect2, pindel, varscan2
- FKBP15 | c.2969_2992del p.E990_Q997del | In Frame Del (DEL) | VAF 38/72 reads (53%) | called by mutect2, pindel, varscan2
- HTR1A | c.272_273delinsT p.P91Lfs*17 | Frame Shift Del (DEL) | VAF 17/37 reads (46%) | called by pindel, varscan2*
- OR7A10 | c.342_358del p.L115* | Frame Shift Del (DEL) | VAF 74/367 reads (20%) | called by mutect2, pindel, varscan2
- RBM15 | c.2378_2402del p.L793Pfs*45 | Frame Shift Del (DEL) | VAF 6/78 reads (8%) | called by mutect2, pindel
- SF3B3 | c.2134-17_2135del p.X712_splice | Splice Site (DEL) | VAF 38/113 reads (34%) | called by mutect2, pindel
- SLC6A8 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- BEST2 | c.123G>A p.G41= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV99244659; called by muse, mutect2
- BRINP3 | c.417T>C p.A139= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV66542852; called by muse, mutect2, varscan2
- CCDC85A | c.930G>C p.L310= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV68155911; called by muse, mutect2
- CPEB3 | c.1893G>A p.L631= | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as rs148506777; called by muse, mutect2, varscan2
- CXADR | c.690C>G p.V230= | Silent (SNP) | VAF 434/1175 reads (37%) | catalogued as rs1442763241, COSV53031552; called by muse, mutect2, varscan2
- DYNC2H1 | c.7224T>C p.A2408= | Silent (SNP) | VAF 104/208 reads (50%) | catalogued as COSV62108248; called by muse, varscan2
- ERCC6 | c.2019G>T p.L673= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV63389178, COSV63394828; called by muse, mutect2, varscan2
- ERVFRD-1 | c.708T>C p.S236= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV65370065; called by muse, mutect2, varscan2
- GSTP1 | c.420C>G p.G140= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV66992971; called by muse, mutect2, varscan2
- LIPE | c.1938G>C p.L646= | Silent (SNP) | VAF 32/56 reads (57%) | catalogued as COSV54925203, COSV54925920; called by muse, mutect2, varscan2
- MAB21L1 | c.267G>A p.V89= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV59827173; called by muse, mutect2, varscan2
- N4BP2L2 | c.1728G>A p.R576= (on ENST00000674422; = p.R147= on NM_033111.4) | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV62635993; called by muse, mutect2, varscan2
- NOL9 | c.1179G>C p.V393= | Silent (SNP) | VAF 21/158 reads (13%) | catalogued as COSV66627105; called by muse, mutect2, varscan2
- NPHP4 | c.3639T>A p.I1213= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV65398395; called by muse, mutect2, varscan2
- OR4L1 | c.900A>G p.K300= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV59851402; called by muse, mutect2, varscan2
- PDE1C | c.927G>A p.L309= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as COSV58530847; called by muse, mutect2, varscan2
- SERPINA7 | c.1017A>C p.T339= | Silent (SNP) | VAF 77/168 reads (46%) | catalogued as COSV59667515; called by muse, mutect2, varscan2
- SHROOM4 | c.321G>T p.L107= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV56798036; called by muse, mutect2, varscan2
- SLC35F6 | c.345C>T p.S115= | Silent (SNP) | VAF 99/261 reads (38%) | catalogued as rs768698894, COSV60426127; called by muse, mutect2, varscan2
- SYNE1 | c.19581A>G p.Q6527= (on ENST00000367255 / NM_182961.4; = p.Q6456= on NM_033071.3) | Silent (SNP) | VAF 28/574 reads (5%) | catalogued as rs1055929201, COSV55117909; called by muse, mutect2
- TEX10 | c.2637C>T p.T879= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs913684207, COSV52450968; called by muse, mutect2, varscan2
- TTBK2 | c.2271A>G p.K757= | Silent (SNP) | VAF 82/275 reads (30%) | catalogued as COSV51182373, COSV99141136; called by muse, mutect2, varscan2
- ZNF595 | c.1128C>G p.A376= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as COSV59554271; called by muse, mutect2, varscan2
- ATP8A2 | c.1662+27A>T | Intron (SNP) | VAF 51/125 reads (41%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.740A>G | RNA (SNP) | VAF 117/423 reads (28%) | catalogued as rs780407795; called by muse, mutect2, varscan2
- RBM44 | c.-98-1909G>A | Intron (SNP) | VAF 85/124 reads (69%) | catalogued as rs977247452, COSV57633690; called by muse, mutect2, varscan2
- SUMF2 | c.733+304G>A | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as rs370810923, COSV51919274; called by muse, mutect2
